Somatic mutation profile of tumor specimen BA2086D (aliquot aq-BA2086D) from BEATAML1.0 case 2169, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 69.7 years (25,457 days).
Specimen BA2086D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 79143b07-4e63-4a09-9dc3-fd2a79b04bbf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2105D (Solid Tissue Normal), aliquot aq-BA2105D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a765e46b-3077-41b7-9e8e-db38b4184541

The open-access MAF lists 26 somatic variants for this specimen: 19 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 3, Splice Site 2, Nonsense Mutation 2, 5'UTR 2, Intron 1, Translation Start Site 1, 3'UTR 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP2A1 | c.2464dup p.R822Pfs*39 | Frame Shift Ins (INS) | VAF 20/60 reads (33%) | catalogued as rs751365374; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 60/138 reads (43%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS15 | c.2095G>A p.V699M | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1318520551; called by muse, mutect2, varscan2
- C4orf54 | c.3082G>T p.E1028* | Nonsense Mutation (SNP) | VAF 4/50 reads (8%) | catalogued as COSV72766671; called by muse, mutect2
- EYS | c.6019C>A p.L2007M | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.094); catalogued as COSV65469421; called by muse, mutect2, varscan2
- FLT3 | c.2027A>C p.N676T | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV54047682, COSV54069454; called by muse, mutect2
- FLT3 | c.1352C>T p.S451F | Missense Mutation (SNP) | VAF 25/193 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as COSV54046796; called by muse, mutect2, varscan2
- IZUMO1R | c.352C>T p.R118* (on ENST00000440961; = p.R125* on NM_001199206.3) | Nonsense Mutation (SNP) | VAF 32/59 reads (54%) | catalogued as rs190330179; called by muse, mutect2, varscan2
- MYL5 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 68/148 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.338); catalogued as rs765244059, COSV59140296; called by muse, mutect2, varscan2
- MYO18A | c.3075G>A p.M1025I | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62871791; called by mutect2, varscan2
- SHPRH | c.2021G>T p.R674L | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV51611839; called by muse, mutect2
- STRC | c.3794+1G>A p.X1265_splice | Splice Site (SNP) | VAF 32/159 reads (20%) | catalogued as rs777192662; called by muse, mutect2, varscan2
- ADCY6 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 6/100 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.838); called by muse, mutect2
- DNMT3A | c.1932_1936+5del p.X644_splice | Splice Site (DEL) | VAF 18/55 reads (33%) | called by mutect2, pindel, varscan2
- DUOX2 | c.2852-4C>T | Splice Region (SNP) | VAF 121/295 reads (41%) | called by muse, mutect2, varscan2
- L3MBTL4 | c.1715G>T p.G572V | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LTB4R | c.1056C>A p.N352K | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2
- RCVRN | c.382G>T p.A128S | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.149); called by muse, mutect2
- SMC3 | c.2099T>G p.L700R | Missense Mutation (SNP) | VAF 70/169 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KCNK2 | c.51G>A p.A17= (on ENST00000444842 / NM_001017425.3; = p.A2= on NM_014217.4) | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as rs758535898, COSV67206863; called by muse, mutect2, varscan2
- MISP | c.2019C>T p.Y673= | Silent (SNP) | VAF 56/108 reads (52%) | catalogued as rs150909199; called by muse, mutect2, varscan2
- MUC22 | c.3678C>T p.T1226= | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as rs1188534235; called by muse, mutect2, varscan2
- GPR146 | c.-111C>T | 5'UTR (SNP) | VAF 21/63 reads (33%) | called by muse, mutect2, varscan2
- OLFM1 | c.-41C>A | 5'UTR (SNP) | VAF 4/18 reads (22%) | called by mutect2, varscan2
- SH2D3C | c.516-5307G>T | Intron (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- TRDC | c.*75C>A | 3'UTR (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
